Somatic mutation profile of tumor specimen MP2PRT-PASXGB-TMP1-A (aliquot MP2PRT-PASXGB-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASXGB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,228 days).
Specimen MP2PRT-PASXGB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41c9aba3-ac0a-4d95-accd-74c97f594d21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASXGB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASXGB-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f776d8f-623d-4361-a648-43f6d0eb04ec

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 8, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD17B1 | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 32/956 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99864942; called by muse, mutect2
- SLITRK2 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59425251, COSV59428776; called by muse, mutect2
- ZNF177 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 20/489 reads (4%) | catalogued as COSV100606285; called by muse, mutect2
- CPS1 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 11/390 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FAM13C | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HECTD1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- LRP1B | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 97/472 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RLF | c.4840G>A p.E1614K | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- USP24 | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CARF | c.1587C>G p.T529= | Silent (SNP) | VAF 14/308 reads (5%) | called by muse, mutect2
- CCL3L3 | c.201C>A p.T67= | Silent (SNP) | VAF 67/475 reads (14%) | called by muse, mutect2, varscan2
- LUM | c.24C>T p.L8= | Silent (SNP) | VAF 52/227 reads (23%) | catalogued as COSV99898846; called by muse, mutect2, varscan2
- MPDZ | c.4011C>T p.I1337= | Silent (SNP) | VAF 21/195 reads (11%) | called by muse, mutect2, varscan2
- NFKBID | c.339C>T p.A113= (on ENST00000396901; = p.A265= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 140/486 reads (29%) | catalogued as rs770936566; called by muse, varscan2
- NOMO3 | c.972C>T p.F324= | Silent (SNP) | VAF 18/443 reads (4%) | called by muse, mutect2
